Somatic mutation profile of tumor specimen TCGA-WC-AA9A-01A (aliquot TCGA-WC-AA9A-01A-11D-A39W-08) from TCGA case TCGA-WC-AA9A, project TCGA-UVM (Uveal Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Spindle cell melanoma, NOS; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIA; Age at diagnosis: 70.2 years (25,641 days).
Specimen TCGA-WC-AA9A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bf182868-3ef8-4bc0-bb18-853155a094ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WC-AA9A-10A (Blood Derived Normal), aliquot TCGA-WC-AA9A-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/52b2e952-efc4-4e43-87c6-c38e795f2c30

The open-access MAF lists 8 somatic variants for this specimen: 8 protein-altering or splice-affecting.
By variant classification: Missense Mutation 7, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNA11 | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 16/49 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1057519742, COSV50017277, COSV50017623, COSV50017882; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.1997A>C p.K666T | Missense Mutation (SNP) | VAF 28/63 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs374250186, COSV59205833, COSV59206062, COSV59207657; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BAP1 | c.553G>C p.G185R | Missense Mutation (SNP) | VAF 22/22 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV56230214; called by muse, mutect2, varscan2
- CNPY2 | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 100/220 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs768166554, COSV99076045; called by muse, mutect2, varscan2
- FLRT1 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs771760157, COSV55358981; called by muse, mutect2, varscan2
- APC | c.8411A>C p.Q2804P | Missense Mutation (SNP) | VAF 47/87 reads (54%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FBXL17 | c.1946G>T p.G649V | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TPCN1 | c.1506C>G p.Y502* | Nonsense Mutation (SNP) | VAF 43/72 reads (60%) | called by muse, mutect2, varscan2
